Somatic mutation profile of tumor specimen TCGA-FD-A62N-01A (aliquot TCGA-FD-A62N-01A-11D-A30E-08) from TCGA case TCGA-FD-A62N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.3 years (25,297 days).
Specimen TCGA-FD-A62N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7eab38b-5dad-4f7d-a287-f5f05ae45f37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A62N-10A (Blood Derived Normal), aliquot TCGA-FD-A62N-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96cc3034-85c4-425d-9f78-25949f78d63c

The open-access MAF lists 105 somatic variants for this specimen: 77 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 27, Splice Site 6, Nonsense Mutation 5, Frame Shift Del 5, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD2 | c.5068C>T p.R1690* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as rs761127171, COSV101245737; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1814+1G>T p.X605_splice | Splice Site (SNP) | VAF 9/41 reads (22%) | hotspot (GDC flag); catalogued as CD952454, CS961682, COSV57294691, COSV57319332; called by muse, mutect2, varscan2
- RHOA | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 17/142 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV69042626; called by muse, mutect2, varscan2
- ANAPC5 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs139334549; called by muse, mutect2, varscan2
- ANK1 | c.5097-2A>G p.X1699_splice | Splice Site (SNP) | VAF 12/53 reads (23%) | catalogued as COSV55890237; called by muse, mutect2, varscan2
- ANKFN1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 19/115 reads (17%) | catalogued as COSV100593920; called by muse, mutect2, varscan2
- ARFGEF1 | c.4129G>A p.V1377M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV51614386; called by muse, mutect2, varscan2
- ARMC2 | c.2207C>G p.S736C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64552681; called by muse, mutect2, varscan2
- ATP6V1A | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs760842074, COSV56363714; called by muse, mutect2, varscan2
- BPIFA3 | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.462); catalogued as COSV64926116; called by muse, mutect2
- CACHD1 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766888980, COSV51550513; called by muse, mutect2, varscan2
- CAMTA1 | c.3179C>G p.S1060* | Nonsense Mutation (SNP) | VAF 22/143 reads (15%) | catalogued as COSV100351762; called by muse, mutect2, varscan2
- CCDC190 | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs371986435; called by muse, mutect2, varscan2
- CNOT2 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV57505546; called by muse, mutect2
- CNTF | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV60161014; called by muse, mutect2, varscan2
- COL22A1 | c.753G>T p.L251F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV57351689; called by muse, mutect2, varscan2
- COPS2 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs745372669, COSV54644537, COSV54646082; called by muse, mutect2, varscan2
- CSAG1 | c.166A>T p.R56W | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV63400863; called by muse, mutect2, varscan2
- DCAF1 | c.4141G>T p.D1381Y | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60045500; called by muse, mutect2, varscan2
- DCSTAMP | c.1405A>C p.K469Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52579225; called by muse, mutect2, varscan2
- DGKG | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs200662645; called by muse, mutect2
- DGKG | c.705C>A p.D235E | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV53969928; called by muse, mutect2
- FOXR2 | c.927T>G p.F309L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100189574; called by muse, mutect2
- GIMAP4 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as COSV55433975; called by muse, mutect2, varscan2
- GTSF1 | c.118-1G>A p.X40_splice | Splice Site (SNP) | VAF 11/60 reads (18%) | catalogued as COSV59939175; called by muse, mutect2, varscan2
- HK2 | c.1808C>A p.S603Y | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51875448, COSV51878052; called by muse, mutect2, varscan2
- HMCN1 | c.10538G>A p.G3513E | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV54926257; called by muse, mutect2, varscan2
- HTR5A | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs753593458, COSV55285953; called by muse, mutect2, varscan2
- INTS2 | c.2800C>G p.Q934E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99248546; called by muse, mutect2
- LILRB4 | c.907G>T p.G303W | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200205238, COSV54407553; called by muse, mutect2, varscan2
- METTL25 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs980445007, COSV99942584; called by muse, mutect2
- MMP2 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs147336184, COSV54603907; called by muse, mutect2, varscan2
- MMUT | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.021); catalogued as rs148285323, CM1510868, COSV51273173; called by muse, mutect2, varscan2
- MYO1A | c.623C>A p.A208E | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55656339; called by muse, mutect2, varscan2
- MYO3A | c.4141A>G p.T1381A | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771244264, COSV56342574; called by muse, mutect2, varscan2
- OR4C16 | c.580A>T p.N194Y | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58943414; called by muse, mutect2, varscan2
- OR7A5 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as rs138181742; called by muse, mutect2
- PCNX3 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs989472796, COSV58419738; called by muse, mutect2
- PGAM4 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100431267, COSV58451268; called by muse, mutect2, varscan2
- PKHD1L1 | c.7552A>G p.I2518V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs1421514371, COSV65749317; called by muse, mutect2, varscan2
- PLEKHG3 | c.396C>T p.P132= (on ENST00000394691; = p.P188= on NM_001308147.2) | Splice Region (SNP) | VAF 5/36 reads (14%) | catalogued as COSV55982343; called by muse, mutect2, varscan2
- PLXDC2 | c.1171C>T p.R391* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as rs1335007275, COSV65905846; called by muse, mutect2, varscan2
- PRDM16 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV54602714; called by muse, mutect2, varscan2
- PRICKLE1 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as rs1566076344, COSV58204942; called by muse, mutect2, varscan2
- PTDSS1 | c.524G>C p.G175A | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61265911; called by muse, mutect2
- QPRT | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.755); catalogued as rs745444576, COSV54880292; called by muse, mutect2, varscan2
- RDX | c.1387T>G p.L463V | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.9); catalogued as COSV58195673; called by muse, mutect2, varscan2
- RTCA | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV53121712; called by muse, mutect2, varscan2
- SAGE1 | c.1338G>A p.M446I | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV61016035; called by muse, mutect2, varscan2
- SLC22A10 | c.345del p.C116Vfs*17 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | catalogued as rs748140007; called by mutect2, pindel, varscan2
- SLC22A4 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52359575; called by muse, mutect2, varscan2
- SLC27A1 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53099464; called by muse, mutect2
- SLC34A1 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs576880299, COSV60998123; called by muse, mutect2, varscan2
- SLFN11 | c.413C>G p.T138S | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as COSV57699949; called by muse, mutect2, varscan2
- SMC1A | c.2273G>C p.R758P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59131136; called by muse, mutect2, varscan2
- SNTG2 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57998809; called by muse, mutect2, varscan2
- SORCS1 | c.3371+1G>T p.X1124_splice | Splice Site (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99548747; called by muse, mutect2
- SRPK3 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV54209286; called by muse, mutect2, varscan2
- TENT4A | c.1932G>A p.M644I | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.132); catalogued as rs1316365242, COSV50098201; called by muse, mutect2
- TMEM200A | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV51657010; called by muse, mutect2, varscan2
- TNC | c.3710G>A p.G1237E | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144004485; called by muse, mutect2
- TNPO1 | c.2590-3_2590-1del p.X864_splice | Splice Site (DEL) | VAF 8/72 reads (11%) | catalogued as COSV61523241; called by mutect2, pindel
- TP53 | c.459del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as COSV52700360, COSV52751929; called by mutect2, pindel, varscan2
- TSPYL4 | c.829A>T p.R277W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60310806; called by muse, mutect2, varscan2
- TTN | c.33430A>T p.K11144* (on ENST00000591111; = p.K10217* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100623135; called by muse, mutect2
- USP33 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62470764; called by muse, mutect2
- VWF | c.4436G>A p.G1479D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.118); catalogued as COSV54629666; called by muse, mutect2, varscan2
- WDR43 | c.1738A>G p.T580A | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101333050; called by muse, mutect2, varscan2
- XAB2 | c.1972-2A>G p.X658_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as COSV50346819; called by muse, mutect2, varscan2
- YWHAZ | c.248G>T p.R83I | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV62054642; called by muse, mutect2, varscan2
- ZBTB3 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101188998; called by muse, mutect2
- ZNF385D | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99875780, COSV99876754; called by muse, mutect2
- ZNF507 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1402069813, COSV61332679; called by muse, mutect2, varscan2
- ASAH2 | c.1230A>C p.E410D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- KIAA0319 | c.2610_2613del p.V871Rfs*35 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- SSRP1 | c.582del p.T195Rfs*14 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- TP53 | c.131_143del p.M44Tfs*75 | Frame Shift Del (DEL) | VAF 34/352 reads (10%) | called by mutect2, pindel
- ADAMTS16 | c.826C>A p.R276= | Silent (SNP) | VAF 82/205 reads (40%) | catalogued as rs1481340390, COSV57001176, COSV57001879; called by muse, mutect2, varscan2
- ADAMTS16 | c.2997A>C p.S999= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV57001196; called by muse, mutect2
- ALPL | c.123G>A p.L41= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100876932; called by muse, mutect2
- ARHGAP15 | c.621C>T p.I207= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV54512798; called by muse, mutect2, varscan2
- ATP4A | c.2400C>T p.P800= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV52870500; called by muse, mutect2, varscan2
- CLCA4 | c.1527T>A p.I509= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV55370001; called by muse, mutect2, varscan2
- CNKSR2 | c.1299T>G p.T433= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV54258810, COSV99668737; called by muse, mutect2, varscan2
- EGR1 | c.48C>T p.I16= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs1413767577, COSV53520778, COSV99525580; called by muse, varscan2
- FXYD5 | c.474C>T p.I158= | Silent (SNP) | VAF 26/207 reads (13%) | catalogued as COSV61569522; called by muse, mutect2, varscan2
- INPPL1 | c.2535C>T p.I845= | Silent (SNP) | VAF 26/234 reads (11%) | catalogued as rs375358684; called by muse, mutect2, varscan2
- INSRR | c.2112G>T p.A704= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV63876091; called by muse, mutect2
- ITIH5 | c.252G>A p.E84= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as COSV56906214; called by muse, mutect2, varscan2
- LAMA3 | c.7968G>A p.V2656= (on ENST00000313654 / NM_198129.4; = p.V1047= on NM_000227.6) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV52539963; called by muse, mutect2, varscan2
- MCM3AP | c.1467G>A p.K489= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV52443730; called by muse, mutect2, varscan2
- MYO1G | c.2451C>T p.A817= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs756514864, COSV51856262; called by muse, mutect2, varscan2
- NANOS3 | c.474C>G p.A158= (on ENST00000397555; = p.A177= on NM_001098622.2) | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV59248481; called by muse, mutect2
- OR11G2 | c.810T>A p.A270= | Silent (SNP) | VAF 25/190 reads (13%) | catalogued as COSV62132855; called by muse, mutect2, varscan2
- OR2T1 | c.850C>T p.L284= | Silent (SNP) | VAF 19/210 reads (9%) | catalogued as COSV63542582; called by muse, mutect2
- PSMD8 | c.252G>T p.S84= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV53051982, COSV53054942; called by muse, mutect2, varscan2
- PTPRG | c.1899T>A p.T633= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99876320; called by muse, mutect2
- RAB33A | c.234G>A p.V78= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV57061968, COSV57062948; called by muse, mutect2, varscan2
- SAMD4B | c.1380G>A p.E460= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV58752783; called by muse, mutect2
- SCML4 | c.585C>T p.S195= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV64633626, COSV64637110; called by muse, mutect2
- STRIP1 | c.864G>A p.L288= | Silent (SNP) | VAF 23/229 reads (10%) | catalogued as COSV63929977; called by muse, mutect2, varscan2
- SUPT5H | c.3252C>T p.L1084= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV58680227; called by muse, varscan2
- TAS1R1 | c.2463C>A p.L821= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV59840387; called by muse, mutect2, varscan2
- UNC45B | c.1407C>A p.I469= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs1445777949, COSV52099018; called by muse, mutect2, varscan2
- OBSCN | c.11659+3589G>C | Intron (SNP) | VAF 11/106 reads (10%) | catalogued as COSV52808128; called by muse, mutect2
